Somatic mutation profile of tumor specimen TCGA-EE-A3AF-06A (aliquot TCGA-EE-A3AF-06A-11D-A196-08) from TCGA case TCGA-EE-A3AF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 48.5 years (17,731 days).
Specimen TCGA-EE-A3AF-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a07d4ff9-e02b-46f2-b00a-e8fdcb3afa4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3AF-10A (Blood Derived Normal), aliquot TCGA-EE-A3AF-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14496e3c-58f5-44fc-b3de-72797401ba60

The open-access MAF lists 1,206 somatic variants for this specimen: 825 protein-altering or splice-affecting, 361 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 757, Silent 361, Nonsense Mutation 40, Splice Region 9, Frame Shift Del 9, Splice Site 8, Intron 8, 5'Flank 4, RNA 4, 3'Flank 3, Translation Start Site 1, 3'UTR 1.

Variants (750 of 1,206; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 37/91 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- ARID1A | c.6260G>A p.G2087E | Missense Mutation (SNP) | VAF 38/92 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253928, COSV61375511; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DDX3X | c.1420C>T p.R474C (on ENST00000399959; = p.R475C on NM_001356.5) | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1064794574, CM158049, COSV67864105; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDNRB | c.1283C>T p.P428L (on ENST00000377211 / NM_001201397.1; = p.P338L on NM_000115.5) | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1566304640, COSV57527351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.1921T>A p.Y641N (on ENST00000460911 / NM_001203247.2; = p.Y646N on NM_004456.5) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs267601395, COSV57445793, COSV57445823, COSV57462051; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs867619972, COSV51760182; called by muse, mutect2, varscan2
- ABCA4 | c.6005G>A p.S2002N | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64677199; called by muse, mutect2, varscan2
- ABCB11 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as COSV55599261; called by muse, mutect2, varscan2
- AC139530.2 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs756443745, COSV100230821; called by muse, mutect2, varscan2
- ACKR2 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs1204888735, COSV99825801; called by muse, mutect2, varscan2
- ACKR2 | c.111G>C p.R37S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs761897179, COSV99825803; called by muse, mutect2, varscan2
- ACOX3 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 84/257 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62713528; called by muse, mutect2, varscan2
- ACSM1 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV54639483; called by muse, mutect2, varscan2
- ACVRL1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM040655, COSV101187810, COSV66360942; called by muse, mutect2, varscan2
- ADAMTS19 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50756448, COSV50790161; called by muse, mutect2, varscan2
- ADAMTS3 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749717867, COSV54400766; called by muse, mutect2, varscan2
- ADGRB3 | c.4053G>T p.M1351I | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53240162, COSV53257873; called by muse, mutect2, varscan2
- ADGRF1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV100982625, COSV100982700; called by muse, mutect2, varscan2
- ADGRF1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100982701; called by muse, mutect2, varscan2
- ADGRG5 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100446530; called by muse, mutect2, varscan2
- ADGRG5 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61082615; called by muse, mutect2, varscan2
- ADGRL2 | c.3275G>A p.R1092Q (on ENST00000370717 / NM_001366005.1; = p.R1079Q on NM_012302.4) | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs767737569, COSV54654551; called by muse, mutect2, varscan2
- ADGRV1 | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs761612567, COSV67988588; called by muse, mutect2, varscan2
- AFAP1L1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.084); catalogued as COSV57047386, COSV57048129; called by muse, mutect2, varscan2
- AFAP1L1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57047391; called by muse, mutect2, varscan2
- AGBL1 | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV66870696; called by muse, mutect2, varscan2
- AGMO | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1421781334, COSV61122443; called by muse, mutect2, varscan2
- AKR1D1 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 37/86 reads (43%) | catalogued as COSV54338891, COSV54339447; called by muse, mutect2, varscan2
- ALDH1L1 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56418572; called by muse, mutect2, varscan2
- ALDH3B2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62428536; called by muse, mutect2
- ALMS1 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV52501943; called by muse, mutect2, varscan2
- ALOX15B | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV66480067; called by muse, mutect2, varscan2
- AMOTL2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51440640; called by muse, mutect2, varscan2
- AMPD1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62418344; called by muse, mutect2, varscan2
- ANAPC7 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 149/391 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV101484777, COSV71443742; called by muse, mutect2, varscan2
- ANKEF1 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 72/166 reads (43%) | catalogued as rs1388412987, COSV65693505; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5945C>T p.T1982I | Missense Mutation (SNP) | VAF 112/292 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as COSV51856818; called by muse, mutect2, varscan2
- ANO2 | c.514G>A p.D172N (on ENST00000356134 / NM_001278597.3; = p.D176N on NM_001278596.3) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59008320; called by muse, mutect2, varscan2
- ANO3 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56806121; called by muse, mutect2, varscan2
- ANXA11 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55418162; called by muse, mutect2, varscan2
- AOC2 | c.2215C>T p.P739S (on ENST00000253799 / NM_009590.4; = p.P712S on NM_001158.5) | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1345101929, COSV99520453; called by muse, mutect2, varscan2
- AP3S1 | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV57474905, COSV57476919; called by muse, mutect2, varscan2
- APLNR | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as COSV57243852; called by muse, mutect2, varscan2
- APOB | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51949891; called by muse, mutect2, varscan2
- APOBEC3B | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100213816; called by muse, mutect2, varscan2
- AREG | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV99144397; called by muse, mutect2, varscan2
- ARHGAP21 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57605752; called by muse, mutect2, varscan2
- ARHGAP31 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.589); catalogued as COSV51798020, COSV51798091, COSV99956673; called by muse, mutect2, varscan2
- ARHGAP32 | c.1994A>G p.N665S (on ENST00000310343 / NM_001378025.1; = p.N316S on NM_014715.4) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs765139019, COSV59854721; called by muse, mutect2, varscan2
- ARHGAP6 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV57298523; called by muse, mutect2, varscan2
- ARHGEF2 | c.1341C>A p.N447K (on ENST00000361247 / NM_001162383.2; = p.N419K on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58116498; called by muse, mutect2, varscan2
- ARHGEF5 | c.4474C>T p.R1492W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753838118; called by muse, varscan2
- ARID1B | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV51677733; called by muse, mutect2, varscan2
- ARID2 | c.5026C>T p.Q1676* | Nonsense Mutation (SNP) | VAF 57/185 reads (31%) | catalogued as COSV57595770, COSV57612767; called by muse, mutect2, varscan2
- ARMC4 | c.2155T>G p.L719V | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59472300; called by muse, mutect2, varscan2
- ARMCX2 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV57531033; called by muse, mutect2, varscan2
- ARSF | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV63840872; called by muse, mutect2, varscan2
- ARX | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66875409; called by muse, mutect2, varscan2
- ASAP2 | c.2902G>A p.G968R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99432201; called by muse, mutect2, varscan2
- ASXL3 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); catalogued as COSV52460274; called by muse, mutect2, varscan2
- ASXL3 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV99325210; called by muse, mutect2, varscan2
- ASXL3 | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.029); catalogued as COSV52465452; called by muse, mutect2, varscan2
- ATAT1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1335707544, COSV53313264; called by muse, mutect2, varscan2
- ATF6B | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64352566; called by muse, mutect2, varscan2
- ATG2A | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101034873; called by muse, varscan2
- ATM | c.8810T>G p.V2937G | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53730082, COSV53759641; called by muse, mutect2, varscan2
- ATP10A | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1186917803, COSV63522908; called by muse, mutect2, varscan2
- ATP10B | c.3531G>C p.L1177F | Missense Mutation (SNP) | VAF 144/409 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100514948, COSV59163032; called by muse, mutect2, varscan2
- ATP12A | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54522044; called by muse, mutect2, varscan2
- ATP1A2 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63405656; called by muse, mutect2, varscan2
- ATP2B4 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); catalogued as rs779601653, COSV58175453; called by muse, mutect2, varscan2
- ATP6V1G3 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1304557759, COSV55280510; called by muse, mutect2
- AXDND1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV62647499; called by muse, mutect2
- B3GAT3 | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53884360; called by muse, mutect2, varscan2
- B4GALNT4 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs778775824, COSV100327903; called by muse, mutect2, varscan2
- B4GALT2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs539906206, COSV58844870; called by muse, mutect2, varscan2
- B4GALT3 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV60527623, COSV60527892; called by muse, mutect2, varscan2
- BACH2 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.163); catalogued as rs144153232; called by muse, mutect2, varscan2
- BACH2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV100001229; called by muse, mutect2, varscan2
- BAG6 | c.3382C>T p.R1128W (on ENST00000676571; = p.R1081W on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/206 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs751639269, COSV99277716; called by muse, mutect2, varscan2
- BARX2 | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.121); catalogued as COSV55652179; called by muse, mutect2, varscan2
- BARX2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55651171; called by muse, mutect2
- BAZ2B | c.3184C>T p.P1062S | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54276605; called by muse, mutect2, varscan2
- BCHE | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.275); catalogued as CM960159, COSV104387690, COSV52261216; called by muse, mutect2, varscan2
- BCL11A | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV59635911; called by muse, mutect2, varscan2
- BCL2L15 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.846); catalogued as COSV63643003; called by muse, mutect2, varscan2
- BCL9L | c.4112C>T p.P1371L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs753922655, COSV52688634; called by muse, mutect2, varscan2
- BCL9L | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1157752576, COSV52688644; called by muse, mutect2, varscan2
- BCOR | c.3382C>T p.P1128S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.632); catalogued as COSV60716589; called by muse, mutect2, varscan2
- BEST1 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281865262, CD073573, CM024218, CM124789, COSV56446435; ClinVar: not provided; called by muse, mutect2, varscan2
- BGN | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV59038223; called by muse, mutect2
- BIVM-ERCC5 | c.4526C>T p.T1509I | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.987); catalogued as COSV63247120; called by muse, mutect2, varscan2
- BNC2 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV66155669; called by muse, mutect2, varscan2
- BPIFB1 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53606087; called by muse, mutect2, varscan2
- BRD1 | c.3152C>T p.T1051I (on ENST00000216267 / NM_001349940.1; = p.T1182I on NM_001304808.3) | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1341834739, COSV99350402; called by muse, varscan2
- BRD8 | c.3665G>A p.G1222E | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); catalogued as COSV54522301; called by muse, mutect2, varscan2
- BRD8 | c.3664G>A p.G1222R | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV99497048; called by muse, mutect2, varscan2
- BSN | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99609992; called by muse, mutect2, varscan2
- BSN | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99609994; called by muse, mutect2, varscan2
- BTBD11 | c.1915C>T p.H639Y (on ENST00000280758 / NM_001018072.2; = p.H176Y on NM_001017523.2) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.908); catalogued as COSV55031981; called by muse, mutect2, varscan2
- BTBD11 | c.2096G>A p.G699E (on ENST00000280758 / NM_001018072.2; = p.G236E on NM_001017523.2) | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603282, COSV55021617; called by muse, mutect2, varscan2
- C16orf90 | c.133G>A p.E45K (on ENST00000399645 / NM_001353385.2; = p.E36K on NM_001080524.2) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); catalogued as rs558944359, COSV68714626; called by muse, mutect2, varscan2
- C1QL1 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53648017; called by muse, mutect2, varscan2
- C2CD2 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100298466; called by muse, mutect2, varscan2
- C4orf17 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs867659945, COSV58513410; called by muse, mutect2, varscan2
- C7 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57479866; called by muse, mutect2, varscan2
- CACNA1A | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.075); catalogued as rs887308405, COSV64202761; called by muse, mutect2, varscan2
- CACNA1D | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as rs556582252, COSV55462632; called by muse, varscan2
- CACNA1H | c.6140G>A p.R2047K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV52357635; called by muse, mutect2
- CACNA1I | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV60817097; called by muse, mutect2, varscan2
- CACNA1S | c.2780C>T p.T927I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100755419; called by muse, mutect2
- CAD | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV53031208; called by muse, mutect2, varscan2
- CADPS | c.3499G>A p.D1167N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200712817, COSV51899321; called by muse, mutect2, varscan2
- CAPN6 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60696883; called by muse, mutect2, varscan2
- CAPN9 | c.1829C>T p.T610I | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV55238801; called by muse, mutect2, varscan2
- CARD6 | c.2764G>A p.G922S | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs763856514, COSV54568686; called by muse, mutect2, varscan2
- CARF | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as COSV57549595; called by muse, mutect2, varscan2
- CARS1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV53460104; called by muse, mutect2, varscan2
- CAST | c.538C>T p.P180S (on ENST00000341926; = p.P263S on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57788945; called by muse, mutect2, varscan2
- CATSPERB | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as rs775892294, COSV99831887; called by muse, mutect2, varscan2
- CCAR1 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs370481782; called by muse, mutect2, varscan2
- CCDC130 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as COSV99237875; called by muse, mutect2, varscan2
- CCDC146 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs552375827, COSV53544047, COSV99035595; called by muse, mutect2, varscan2
- CCDC51 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV56493558; called by muse, mutect2, varscan2
- CCDC85A | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1441524080, COSV68155054; called by muse, mutect2, varscan2
- CCN6 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 60/101 reads (59%) | catalogued as COSV57890363; called by muse, mutect2, varscan2
- CD1E | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV63771443, COSV63773077; called by muse, mutect2, varscan2
- CD209 | c.46+1G>A p.X16_splice | Splice Site (SNP) | VAF 90/269 reads (33%) | catalogued as rs375667157; called by muse, mutect2, varscan2
- CD4 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs201040272, COSV50596260; called by muse, mutect2, varscan2
- CD47 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs867558279, COSV62528376; called by muse, mutect2, varscan2
- CDC42BPB | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs754293915, COSV63475450; called by muse, mutect2, varscan2
- CDCA2 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100399211; called by muse, mutect2, varscan2
- CDH18 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.389); catalogued as COSV56899158, COSV56955197; called by muse, mutect2, varscan2
- CDH18 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs747474865, COSV56915440, COSV56955211; called by muse, mutect2, varscan2
- CDH2 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52293905; called by muse, mutect2, varscan2
- CDH22 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64839403; called by muse, mutect2, varscan2
- CDHR2 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); catalogued as rs986931277, COSV56144215; called by muse, mutect2, varscan2
- CEBPG | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52287523; called by muse, mutect2, varscan2
- CENPC | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56625941; called by muse, mutect2, varscan2
- CENPE | c.6492G>A p.M2164I | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV54388722; called by muse, mutect2, varscan2
- CEP164 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV54045726; called by muse, mutect2, varscan2
- CES5A | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs1390010276, COSV51870031; called by muse, mutect2, varscan2
- CFAP58 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV57213440; called by muse, mutect2, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by muse, mutect2, varscan2
- CGN | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs892920338, COSV54973069; called by muse, mutect2, varscan2
- CGNL1 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV55562985, COSV55574108; called by muse, mutect2, varscan2
- CHAMP1 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 115/445 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV63523100; called by muse, mutect2, varscan2
- CHD3 | c.3944C>T p.P1315L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57879579; called by muse, mutect2, varscan2
- CHRM3 | c.1246G>C p.D416H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.959); catalogued as COSV55101431, COSV99697289; called by muse, mutect2, varscan2
- CHRNA4 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.254); catalogued as rs1555837641, COSV64720957; called by muse, mutect2, varscan2
- CKMT2 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV54174748; called by muse, mutect2, varscan2
- CLCNKB | c.1298-1G>A p.X433_splice | Splice Site (SNP) | VAF 46/80 reads (58%) | catalogued as COSV65161724; called by muse, mutect2, varscan2
- CLEC3B | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV56110413; called by muse, mutect2, varscan2
- CLIC4 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65527490; called by muse, mutect2, varscan2
- CNIH4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100837065; called by muse, mutect2, varscan2
- CNIH4 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100837068; called by muse, mutect2, varscan2
- CNTN5 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54341364; called by muse, mutect2, varscan2
- CNTN6 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV63179777, COSV63186987; called by muse, mutect2, varscan2
- CNTNAP1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV52853825; called by muse, mutect2, varscan2
- CNTNAP1 | c.4010C>T p.S1337L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV52853837; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, mutect2, varscan2
- CNTNAP4 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.905); catalogued as COSV56697829; called by muse, mutect2, varscan2
- COL19A1 | c.3373C>T p.P1125S | Missense Mutation (SNP) | VAF 110/185 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59573447, COSV59585359; called by muse, mutect2, varscan2
- COL4A3 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV67419426; called by muse, mutect2, varscan2
- COL5A1 | c.5162A>G p.N1721S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs1482037877, COSV65673818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.4390G>A p.G1464R | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62029346, COSV62035550; called by muse, mutect2, varscan2
- COL9A3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.951); catalogued as COSV100673615; called by muse, mutect2, varscan2
- COX7B | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV63781391; called by muse, mutect2, varscan2
- CPED1 | c.2817G>A p.M939I | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100121600, COSV60014528; called by muse, mutect2, varscan2
- CPED1 | c.2818G>A p.G940R | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121602, COSV60014361; called by muse, mutect2, varscan2
- CPXCR1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV52164333; called by muse, mutect2, varscan2
- CPXM2 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as COSV53869771; called by muse, varscan2
- CRISP2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as COSV59255739, COSV59256565; called by muse, varscan2
- CSDE1 | c.652G>A p.G218S (on ENST00000358528 / NM_001007553.3; = p.G187S on NM_007158.6) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV99796156; called by muse, mutect2, varscan2
- CSMD1 | c.7784T>A p.L2595* (on ENST00000520002; = p.L2594* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV59374391; called by muse, mutect2, varscan2
- CTDSPL2 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99527283; called by muse, mutect2, varscan2
- CTU1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV70292793; called by mutect2, varscan2
- CUEDC1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64227175; called by muse, mutect2, varscan2
- CXXC5 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV56795637; called by muse, mutect2, varscan2
- CYP11B1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as rs749211518, COSV52826058; called by muse, mutect2, varscan2
- CYP19A1 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV53062016; called by muse, mutect2, varscan2
- CYP2A6 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1194609386, COSV56536938; called by muse, varscan2
- DACT1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV60023114; called by muse, mutect2, varscan2
- DAZL | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV51711856, COSV51714569; called by muse, mutect2, varscan2
- DCDC1 | c.5224G>A p.E1742K (on ENST00000597505 / NM_001367979.1; = p.E849K on NM_020869.3) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs764146895, COSV100360827; called by muse, mutect2, varscan2
- DCHS2 | n.2235C>T | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as COSV59733858, COSV59738037; called by muse, mutect2, varscan2
- DDR1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as rs375924272; called by muse, mutect2, varscan2
- DDX59 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV100494416, COSV58753815; called by muse, mutect2, varscan2
- DENND2A | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV52057806; called by muse, varscan2
- DGKB | c.2390G>A p.R797K | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV51763428, COSV51814009; called by muse, mutect2, varscan2
- DHX37 | c.3164C>T p.P1055L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100439562; called by muse, mutect2, varscan2
- DISP1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 112/297 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.291); catalogued as COSV52664142; called by muse, mutect2, varscan2
- DLGAP1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1311806372, COSV59813049; called by muse, mutect2, varscan2
- DLL4 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51070301; called by muse, mutect2, varscan2
- DMBT1 | c.3463G>A p.D1155N (on ENST00000338354 / NM_001377530.1; = p.D656N on NM_004406.3) | Missense Mutation (SNP) | VAF 105/211 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as COSV57558691; called by muse, mutect2, varscan2
- DNAH10 | c.2303G>A p.G768E (on ENST00000409039; = p.G707E on NM_207437.3) | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.139); catalogued as rs571838812, COSV69000138; called by muse, mutect2, varscan2
- DNAH10 | c.10439C>T p.S3480F (on ENST00000409039; = p.S3419F on NM_207437.3) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866149881, COSV68989892; called by muse, mutect2, varscan2
- DNAH11 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60977286; called by muse, mutect2, varscan2
- DNAH11 | c.8927G>A p.R2976Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs370466246; called by muse, mutect2, varscan2
- DNAH17 | c.3661G>A p.E1221K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs753583231, COSV67751712, COSV67754860; called by muse, mutect2, varscan2
- DNAH5 | c.9460G>A p.D3154N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV54208781; called by muse, mutect2, varscan2
- DNAH5 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54223692; called by muse, mutect2, varscan2
- DNAH7 | c.3602T>C p.M1201T | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56782148; called by muse, mutect2, varscan2
- DNAH8 | c.10232G>A p.W3411* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as COSV59475744; called by muse, mutect2, varscan2
- DNAH9 | c.12154T>A p.F4052I | Missense Mutation (SNP) | VAF 111/344 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52372731; called by muse, mutect2, varscan2
- DNTT | c.1008-1G>A p.X336_splice | Splice Site (SNP) | VAF 34/49 reads (69%) | catalogued as COSV64523601; called by muse, mutect2, varscan2
- DOCK3 | c.4943G>A p.G1648E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs866030400, COSV56520703, COSV56546008; called by muse, mutect2, varscan2
- DPF3 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV63502732; called by muse, mutect2, varscan2
- DPP6 | c.2464G>A p.E822K (on ENST00000377770 / NM_001364500.2; = p.E760K on NM_001936.5) | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV59640763; called by muse, mutect2, varscan2
- DPYS | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60911635; called by muse, mutect2, varscan2
- DRD5 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58579815; called by muse, mutect2, varscan2
- DRD5 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58579458; called by muse, mutect2, varscan2
- DRP2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV65811637; called by muse, mutect2, varscan2
- DSCAM | c.5041C>T p.R1681C | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs772705523, COSV68023992; called by muse, mutect2, varscan2
- DSCAML1 | c.5843C>T p.P1948L (on ENST00000321322; = p.P1888L on NM_020693.4) | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV58401269; called by muse, mutect2, varscan2
- DSG2 | c.3226G>A p.V1076M | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV55202332; called by muse, mutect2, varscan2
- DSG3 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57129201; called by muse, mutect2, varscan2
- DSP | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV101131826; called by muse, mutect2, varscan2
- DSP | c.4118C>A p.T1373N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.84); catalogued as COSV65795300; called by muse, mutect2, varscan2
- DSPP | c.136-1G>A p.X46_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99218093; called by muse, mutect2, varscan2
- DSPP | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.023); catalogued as COSV99218096; called by muse, mutect2, varscan2
- DTD1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV66281766; called by muse, mutect2, varscan2
- DYNC1I2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1482166081, COSV55529345; called by muse, mutect2, varscan2
- DYNC2H1 | c.6424G>A p.E2142K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV62104885; called by muse, mutect2, varscan2
- DYRK3 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV65607702; called by muse, mutect2, varscan2
- EBLN2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs776931255, COSV55594871; called by muse, mutect2, varscan2
- EEFSEC | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV54631877; called by muse, mutect2
- EFCAB12 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58178474; called by muse, mutect2, varscan2
- EFNB1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV52662634; called by muse, mutect2, varscan2
- EGFLAM | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV59297844; called by muse, mutect2, varscan2
- EGFLAM | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100380863; called by muse, mutect2, varscan2
- EGFLAM | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380474, COSV100380867, COSV59307811; called by muse, mutect2, varscan2
- ELAC2 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV62033981; called by muse, mutect2, varscan2
- ELMO1 | c.1875G>A p.M625I | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60321305; called by muse, mutect2, varscan2
- ELN | c.1417T>C p.L473= | Splice Region (SNP) | VAF 95/388 reads (24%) | catalogued as COSV52714823; called by muse, mutect2, varscan2
- ELOA2 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.717); catalogued as COSV55307398; called by muse, mutect2, varscan2
- EMID1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV61829181; called by muse, mutect2, varscan2
- EMILIN2 | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1302048193, COSV54426962; called by muse, mutect2, varscan2
- EPAS1 | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV99763708; called by muse, mutect2, varscan2
- EPB41 | c.2437G>A p.E813K (on ENST00000343067 / NM_001166005.2; = p.E537K on NM_004437.4) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV58053024; called by muse, mutect2, varscan2
- EPC2 | c.1488T>G p.N496K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51548592; called by muse, mutect2, varscan2
- EPN2 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV100127774, COSV59060974; called by muse, mutect2, varscan2
- EPPK1 | c.5392G>A p.D1798N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV101599972; called by muse, mutect2, varscan2
- EPPK1 | c.5391G>A p.W1797* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as rs1563881121, COSV101599973; called by muse, mutect2, varscan2
- ERBB4 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53514157, COSV53537187; called by muse, mutect2, varscan2
- ERBB4 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99634523; called by muse, mutect2, varscan2
- EXOSC7 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55557656; called by muse, mutect2, varscan2
- F8 | c.4759G>A p.D1587N | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as rs142347597, COSV64277936; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAF1 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV52955792; called by muse, mutect2, varscan2
- FAM135B | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as rs778940068, COSV50531836; called by muse, mutect2, varscan2
- FAM47A | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV60496090; called by muse, mutect2, varscan2
- FANCM | c.2651C>T p.S884F | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV57500311; called by muse, mutect2, varscan2
- FAT3 | c.3135C>G p.D1045E | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.441); catalogued as COSV53164659; called by muse, mutect2, varscan2
- FBXO40 | c.1811G>A p.R604K | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1158926805, COSV57524351; called by muse, mutect2, varscan2
- FBXO43 | c.1171A>T p.S391C | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV71055309; called by muse, mutect2
- FBXO43 | c.1169A>T p.Q390L | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV71055318; called by muse, mutect2
- FCGBP | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1449980271; called by muse, mutect2, varscan2
- FCRL3 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.13); catalogued as COSV63841878, COSV63842880, COSV63844503; called by muse, mutect2, varscan2
- FGD2 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1418324778, COSV51465742; called by muse, mutect2, varscan2
- FGF11 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99548552; called by muse, mutect2, varscan2
- FGG | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV60196300, COSV60196650; called by muse, mutect2, varscan2
- FHDC1 | c.169T>G p.S57A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV52602604; called by muse, mutect2, varscan2
- FHL1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV61782636; called by muse, mutect2, varscan2
- FHOD1 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV50763370, COSV50767766; called by muse, mutect2, varscan2
- FKBP8 | c.566C>T p.P189L (on ENST00000222308 / NM_001308373.2; = p.P190L on NM_012181.5) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV55893779; called by muse, mutect2, varscan2
- FLNC | c.7604C>T p.S2535L | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs201895675, COSV57963512; ClinVar: uncertain significance; called by mutect2, varscan2
- FMN2 | c.4015G>A p.E1339K | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV60450172; called by muse, mutect2, varscan2
- FMNL3 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53306897; called by muse, mutect2, varscan2
- FN1 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60562339; called by muse, mutect2, varscan2
- FRMPD3 | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.041); catalogued as COSV99347197; called by muse, mutect2, varscan2
- FRMPD4 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66216224; called by muse, mutect2, varscan2
- FSTL5 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as COSV60192893, COSV60224148; called by muse, mutect2, varscan2
- GAA | c.2384A>C p.E795A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.044); catalogued as COSV56410459, COSV56411663; called by muse, mutect2, varscan2
- GABBR1 | c.2120C>T p.P707L | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as COSV63544280; called by muse, mutect2, varscan2
- GAD2 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV52166674; called by muse, mutect2, varscan2
- GALNT7 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778293721, COSV53926558; called by muse, mutect2, varscan2
- GAREM1 | c.2081G>C p.G694A (on ENST00000269209 / NM_001242409.2; = p.G693A on NM_022751.3) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1206882920, COSV52515089; called by muse, mutect2, varscan2
- GBP5 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100600179; called by muse, mutect2, varscan2
- GBP5 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575082350, COSV100600180; called by muse, mutect2, varscan2
- GCAT | c.731+1G>A p.X244_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as rs1264009910, COSV50650039; called by muse, mutect2, varscan2
- GDPD1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52384243; called by muse, mutect2, varscan2
- GDPD2 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65534045; called by muse, mutect2, varscan2
- GFPT2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53806412, COSV53811860; called by muse, mutect2, varscan2
- GHR | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50106373; called by muse, varscan2
- GHRHR | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs984169473, COSV58197915; called by muse, mutect2, varscan2
- GIMAP1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV56188929; called by muse, mutect2, varscan2
- GIPC3 | c.844G>A p.G282R (on ENST00000644946; = p.Q277= on NM_133261.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV59260609; called by muse, mutect2, varscan2
- GLB1L2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs746407023, COSV60280394; called by muse, mutect2, varscan2
- GLRA1 | c.997A>G p.N333D | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV51023779; called by muse, mutect2, varscan2
- GLTPD2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV58702911; called by muse, mutect2, varscan2
- GPAT2 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV64003063; called by muse, mutect2, varscan2
- GPD1L | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56991862, COSV99245847; called by muse, mutect2, varscan2
- GPRIN3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60885416, COSV60886313; called by muse, mutect2, varscan2
- GREB1 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV52195071; called by muse, mutect2, varscan2
- GRM4 | c.1054A>T p.T352S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV65218826; called by muse, mutect2, varscan2
- GSDMB | c.1175G>A p.R392Q (on ENST00000418519 / NM_001165958.1; = p.R370Q on NM_018530.2) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as rs1438333404, COSV58782348; called by muse, mutect2, varscan2
- GSE1 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99497299; called by muse, mutect2, varscan2
- GSG1L | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV101095398; called by muse, mutect2, varscan2
- GUSB | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as COSV59223533; called by muse, mutect2, varscan2
- GZMH | c.600G>A p.G200= | Splice Region (SNP) | VAF 26/82 reads (32%) | catalogued as COSV53539320; called by muse, mutect2, varscan2
- H1-7 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100622276; called by muse, mutect2, varscan2
- H4C7 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55100816; called by muse, mutect2, varscan2
- HBE1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53081014; called by muse, mutect2, varscan2
- HERC1 | c.6786G>C p.Q2262H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV71249897; called by muse, mutect2, varscan2
- HERC2 | c.4283C>T p.P1428L | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV55346260; called by muse, mutect2, varscan2
- HK2 | c.2537G>A p.R846Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs767145519, COSV51875182; called by muse, mutect2, varscan2
- HOOK1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64620681; called by muse, mutect2, varscan2
- HOXB1 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV53318543, COSV99495266; called by muse, mutect2, varscan2
- HOXD3 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV50885092; called by muse, mutect2, varscan2
- HRC | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV53258554; called by muse, mutect2, varscan2
- HRH4 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV56929506; called by muse, mutect2, varscan2
- HSD17B10 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.596); catalogued as COSV51448731; called by muse, mutect2, varscan2
- HSP90AB1 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs890448181, COSV62333223; called by muse, mutect2, varscan2
- HTR4 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867725219, COSV58789896; called by muse, mutect2, varscan2
- HTRA3 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV56469510; called by muse, mutect2, varscan2
- HUWE1 | c.9793G>A p.E3265K | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as COSV53361836; called by muse, mutect2, varscan2
- IBSP | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV56897138; called by muse, mutect2, varscan2
- ICA1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.986); catalogued as rs778660693, COSV55579052; called by muse, mutect2, varscan2
- ICA1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776621478, COSV55575609; called by muse, mutect2, varscan2
- IDH3G | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV99473464; called by muse, mutect2, varscan2
- IGHV1-3 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs561032078; called by muse, mutect2
- IKZF1 | c.588C>T p.S196= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as rs372403425, COSV58782412; called by muse, mutect2, varscan2
- IL13RA1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.407); catalogued as COSV100861761; called by muse, mutect2, varscan2
- IL13RA1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs141752835, COSV65426258; called by muse, mutect2, varscan2
- ILF3 | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as COSV99140392; called by muse, mutect2, varscan2
- IMPG2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV51984515; called by muse, mutect2, varscan2
- INF2 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53036101; called by muse, mutect2, varscan2
- INTS13 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53905113; called by muse, mutect2, varscan2
- IPO5 | c.698A>T p.D233V | Missense Mutation (SNP) | VAF 90/162 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55159020; called by muse, mutect2, varscan2
- IQCA1 | c.1544A>G p.N515S | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs757408719, COSV54506508; called by muse, mutect2, varscan2
- IQGAP2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV57180749; called by muse, mutect2, varscan2
- IQGAP2 | c.2321-1G>A p.X774_splice | Splice Site (SNP) | VAF 47/117 reads (40%) | catalogued as rs772842329, COSV57180756; called by muse, mutect2, varscan2
- IRS4 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64535653; called by muse, mutect2, varscan2
- ITGAL | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV100776322, COSV100776378; called by muse, mutect2, varscan2
- ITGB7 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200281008; called by muse, mutect2, varscan2
- ITIH6 | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99514076; called by muse, mutect2, varscan2
- ITIH6 | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99514078; called by muse, mutect2, varscan2
- KANK4 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.459); catalogued as COSV62988982; called by muse, mutect2
- KBTBD12 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV59681592; called by muse, mutect2, varscan2
- KCNB2 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.175); catalogued as rs867236998, COSV73052586; called by muse, mutect2, varscan2
- KCND2 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs775882947, COSV58600081; called by muse, mutect2, varscan2
- KCND3 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs750895805, COSV56188442; called by muse, mutect2, varscan2
- KCNH8 | c.3136C>T p.L1046F | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV60460585, COSV60474648; called by muse, mutect2, varscan2
- KCNIP1 | c.538G>A p.D180N (on ENST00000411494 / NM_001034837.3; = p.D169N on NM_014592.4) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV61089338; called by muse, mutect2, varscan2
- KCNJ10 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.345); catalogued as COSV63633493; called by muse, mutect2, varscan2
- KCNJ12 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); catalogued as rs1439956093, COSV59172751; called by muse, mutect2
- KCNJ6 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55721589; called by muse, mutect2, varscan2
- KCNJ8 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV53717456, COSV53717695; called by muse, mutect2, varscan2
- KCNN1 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs747964728, COSV55841744; called by muse, mutect2, varscan2
- KCTD11 | c.616C>T p.P206S (on ENST00000333751 / NM_001363642.1; = p.P167S on NM_001002914.2) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs544754992, COSV50141049; called by muse, mutect2, varscan2
- KDM2A | c.2819C>T p.A940V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV58191340; called by muse, mutect2, varscan2
- KDM4A | c.1753T>G p.F585V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV64960527; called by muse, mutect2, varscan2
- KEL | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 137/263 reads (52%) | catalogued as COSV62337416; called by muse, mutect2, varscan2
- KIAA1755 | c.2587C>T p.R863W | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as rs752624978, COSV54075284; called by muse, mutect2, varscan2
- KIF19 | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV100739203; called by muse, mutect2, varscan2
- KIRREL2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV52879647; called by muse, mutect2, varscan2
- KLHDC4 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99566782; called by muse, mutect2, varscan2
- KLHDC4 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99566709; called by muse, mutect2, varscan2
- KLHL13 | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as COSV53244125; called by muse, mutect2, varscan2
- KLHL15 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 78/230 reads (34%) | catalogued as COSV60140521; called by muse, mutect2, varscan2
- KLHL31 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 180/323 reads (56%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.467); catalogued as COSV63882326; called by muse, mutect2, varscan2
- KLRC1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.358); catalogued as COSV61725909; called by muse, mutect2, varscan2
- KMT2A | c.8801T>A p.L2934* | Nonsense Mutation (SNP) | VAF 41/139 reads (29%) | catalogued as COSV63291667; called by muse, mutect2, varscan2
- KRT10 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1414139650, COSV54091247; called by muse, mutect2, varscan2
- KRT34 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1177445427, COSV67450575; called by muse, mutect2, varscan2
- KRT75 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99359679; called by muse, mutect2, varscan2
- KRT76 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); catalogued as COSV60120264, COSV60121756; called by muse, mutect2, varscan2
- LCE1D | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 22/38 reads (58%) | PolyPhen benign (0); catalogued as rs769606443, COSV58271665; called by muse, mutect2, varscan2
- LCN1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.271); catalogued as rs188890815, COSV55019265; called by muse, mutect2, varscan2
- LCNL1 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.979); catalogued as COSV56401311; called by muse, mutect2, varscan2
- LGR4 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60821566; called by muse, mutect2, varscan2
- LHCGR | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs747233599, COSV54292922, COSV54293675; called by muse, mutect2, varscan2
- LILRA1 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV52179439; called by muse, varscan2
- LILRB1 | c.527A>T p.N176I (on ENST00000427581; = p.N140I on NM_006669.6) | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV61121250; called by muse, mutect2, varscan2
- LIMCH1 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV58294840; called by muse, mutect2, varscan2
- LIN7A | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV54025956; called by muse, mutect2, varscan2
- LINGO4 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV64314173; called by muse, mutect2, varscan2
- LIPG | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs748470810, COSV54297892; called by muse, mutect2, varscan2
- LLGL2 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99390596; called by muse, mutect2, varscan2
- LMBR1 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62222872; called by muse, mutect2, varscan2
- LMNB2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV57590588; called by muse, mutect2, varscan2
- LNX1 | c.1441G>C p.G481R (on ENST00000263925 / NM_001126328.3; = p.G385R on NM_032622.2) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV55790831; called by muse, mutect2, varscan2
- LRBA | c.4595T>C p.L1532S | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63963298; called by muse, mutect2, varscan2
- LRRC15 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.309); catalogued as rs185381044, COSV61649564; called by muse, mutect2, varscan2
- LTBP1 | c.3668G>A p.G1223D (on ENST00000404816 / NM_206943.4; = p.G897D on NM_000627.4) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs779937341, COSV55384599; called by muse, mutect2, varscan2
- MAB21L1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 94/179 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1201805948, COSV59816648; called by muse, mutect2, varscan2
- MAB21L3 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1002672669, COSV65674440; called by muse, mutect2, varscan2
- MAGEB4 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV66775167, COSV66776489; called by muse, mutect2, varscan2
- MAGEC1 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); catalogued as rs1295614131, COSV53569766; called by muse, mutect2, varscan2
- MAGI3 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372270961; called by muse, mutect2, varscan2
- MAP3K13 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV53984662; called by muse, mutect2, varscan2
- MARK1 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776989724, COSV65070850; called by muse, mutect2, varscan2
- MCF2 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 109/287 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV58489844, COSV58491464; called by muse, mutect2, varscan2
- MCM3AP | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99387603; called by muse, mutect2, varscan2
- MECOM | c.2227C>T p.P743S (on ENST00000468789 / NM_001105078.4; = p.P931S on NM_004991.4) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV52973118; called by muse, mutect2, varscan2
- MED12 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61353745; called by muse, mutect2
- MED12L | c.2537T>A p.L846Q | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56394241; called by muse, mutect2, varscan2
- MED25 | c.1482C>T p.F494= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as rs185234938; called by muse, mutect2
- METTL7B | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs749574114, COSV57700294; called by muse, mutect2, varscan2
- MFAP4 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV55191670; called by muse, mutect2, varscan2
- MGAM | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554463821, COSV72075580; called by muse, mutect2, varscan2
- MGAM | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101527781; called by muse, varscan2
- MGAT4C | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); catalogued as rs757238970, COSV59834537; called by muse, mutect2, varscan2
- MICAL3 | c.3356T>G p.L1119W | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as COSV71588852; called by muse, mutect2, varscan2
- MIPEP | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV101193044, COSV66301753; called by muse, mutect2, varscan2
- MKS1 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1357107885, COSV58305944; called by muse, mutect2, varscan2
- MMP14 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs766221210, COSV61289412; called by muse, mutect2, varscan2
- MMRN1 | c.2472T>G p.Y824* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV53341778; called by muse, mutect2, varscan2
- MNAT1 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs917666881, COSV54189884; called by muse, mutect2, varscan2
- MPDZ | c.4756C>T p.Q1586* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV59923262; called by muse, mutect2, varscan2
- MSL2 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV53869877; called by muse, mutect2, varscan2
- MTSS1 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100275742; called by muse, mutect2, varscan2
- MUC16 | c.31147G>A p.D10383N | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.263); catalogued as COSV67481206, COSV67489016; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MUC17 | c.6730C>T p.P2244S | Missense Mutation (SNP) | VAF 382/761 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.181); catalogued as COSV60301105; called by muse, mutect2, varscan2
- MUC17 | c.12368C>T p.P4123L | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV60281541; called by muse, mutect2, varscan2
- MUCL3 | c.962C>T p.T321I (on ENST00000304311; = p.T1197I on NM_080870.4) | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.529); catalogued as COSV100424439; called by muse, mutect2, varscan2
- MXRA5 | c.6614C>T p.T2205I | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54248012; called by muse, mutect2, varscan2
- MXRA5 | c.6055G>A p.D2019N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54248027; called by muse, mutect2, varscan2
- MYH13 | c.1907G>A p.G636E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV52824023; called by muse, mutect2, varscan2
- MYH15 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.593); catalogued as COSV56313815; called by muse, mutect2, varscan2
- MYH15 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56318248, COSV99843260; called by muse, mutect2, varscan2
- MYH4 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 158/388 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV55124861; called by muse, mutect2, varscan2
- MYH8 | c.3211G>A p.D1071N | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV67967913; called by muse, mutect2, varscan2
- MYO1C | c.2123A>T p.Y708F (on ENST00000648651 / NM_001080779.2; = p.Y673F on NM_033375.5) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV63000474; called by muse, mutect2, varscan2
- MYO3B | c.3419G>A p.G1140D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs768091244, COSV58715197; called by muse, mutect2, varscan2
- MYO5C | c.1684T>A p.F562I | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55911346; called by muse, mutect2, varscan2
- MYSM1 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.419); catalogued as rs753619199, COSV68978208; called by muse, mutect2, varscan2
- N4BP1 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV52212931; called by muse, mutect2, varscan2
- NAF1 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV56803188, COSV56805823; called by muse, mutect2, varscan2
- NAT10 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 41/87 reads (47%) | catalogued as COSV57665982; called by muse, mutect2, varscan2
- NBEA | c.3536G>A p.G1179D | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV59816642; called by muse, mutect2, varscan2
- NBEA | c.7676C>T p.P2559L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59816659; called by muse, mutect2, varscan2
- NBPF1 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as rs573751808, COSV99845008; called by mutect2, varscan2
- NCF2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100838971, COSV62316586; called by muse, mutect2, varscan2
- NCKAP5 | c.3804G>A p.M1268I | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1477540772, COSV58470734; called by muse, mutect2, varscan2
- NCOA3 | c.3854A>C p.N1285T (on ENST00000371998 / NM_181659.3; = p.N1281T on NM_006534.4) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs774228610, COSV59072685; called by muse, mutect2, varscan2
- NDP | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as CM065337, COSV65203901; called by muse, mutect2, varscan2
- NEB | c.5656G>A p.E1886K | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs746761562, COSV51454582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NETO1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV55014252; called by muse, mutect2, varscan2
- NEU4 | c.1352C>T p.S451F (on ENST00000391969 / NM_001167602.3; = p.S463F on NM_080741.4) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57991668; called by muse, mutect2, varscan2
- NEXMIF | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758482667, COSV50088302, COSV99280577; called by muse, mutect2, varscan2
- NFIA | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64543260; called by muse, varscan2
- NGB | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV53611884; called by muse, mutect2, varscan2
- NHS | c.3787G>A p.D1263N | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); catalogued as COSV66281350; called by muse, mutect2, varscan2
- NHSL2 | c.2072A>T p.Q691L (on ENST00000510661; = p.Q1057L on NM_001013627.2) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV65454750; called by muse, mutect2, varscan2
- NKX3-1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV66512589; called by muse, mutect2, varscan2
- NLRP5 | c.1879C>T p.H627Y | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV66767037; called by muse, mutect2, varscan2
- NME7 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as rs1354415177, COSV63168334; called by muse, mutect2, varscan2
- NME8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs369542497; called by muse, mutect2, varscan2
- NMNAT2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as COSV54271449; called by muse, mutect2, varscan2
- NOMO1 | c.2342C>A p.A781D | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV99814927; called by muse, varscan2
- NOS1 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100501254, COSV57620174; called by muse, mutect2, varscan2
- NPFFR2 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.043); catalogued as COSV58151748; called by muse, mutect2, varscan2
- NPR2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV61314240; called by muse, mutect2, varscan2
- NRIP2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 94/266 reads (35%) | catalogued as rs759845236, COSV61702041; called by muse, mutect2, varscan2
- NRK | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV54605167; called by muse, mutect2, varscan2
- NRXN1 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58484500, COSV58486596; called by muse, mutect2, varscan2
- NUFIP2 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV56605599; called by muse, mutect2, varscan2
- NUP188 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0.187); catalogued as COSV101001514; called by muse, mutect2, varscan2
- NUTM2D | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV67746918; called by muse, mutect2, varscan2
- NXF3 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as COSV67704961; called by muse, mutect2, varscan2
- NYAP1 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.739); catalogued as COSV55721366; called by muse, mutect2, varscan2
- OCRL | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV63981779; called by muse, mutect2, varscan2
- OPCML | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs367841063; called by muse, mutect2, varscan2
- OPRM1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.64); PolyPhen benign (0.304); catalogued as COSV57684337; called by muse, mutect2, varscan2
- OR10A7 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs765788350, COSV58279418; called by muse, mutect2, varscan2
- OR10G8 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs150048996; called by muse, mutect2, varscan2
- OR10H1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV58472783; called by muse, mutect2, varscan2
- OR10H5 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV58279091; called by muse, mutect2, varscan2
- OR10S1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV73343013; called by muse, mutect2, varscan2
- OR10T2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs539828963, COSV57781131, COSV57782220; called by muse, mutect2, varscan2
- OR13C8 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58612292; called by muse, mutect2, varscan2
- OR13G1 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV62943422; called by muse, mutect2, varscan2
- OR1L8 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59187222; called by muse, mutect2, varscan2
- OR2M5 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 135/435 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63546926; called by muse, mutect2, varscan2
- OR2T12 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58775820; called by muse, mutect2, varscan2
- OR2T2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768533956, COSV100737833, COSV61618893; called by mutect2, varscan2
- OR2T35 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1455474001; called by mutect2, varscan2
- OR2W1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 133/227 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs896592244, COSV65851468; called by muse, mutect2, varscan2
- OR4C46 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60218398; called by muse, mutect2, varscan2
- OR4D10 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV73259992; called by muse, mutect2, varscan2
- OR4K2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 65/466 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV53848749, COSV53848767; called by muse, mutect2, varscan2
- OR4K5 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 70/594 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100262414, COSV100262651; called by muse, varscan2
- OR4K5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 96/616 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV60003041; called by muse, varscan2
- OR51L1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58625582; called by muse, mutect2, varscan2
- OR52A5 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56614160; called by muse, mutect2, varscan2
- OR52R1 | c.28T>G p.S10A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV61889290; called by muse, mutect2, varscan2
- OR56A4 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs138873327, COSV58111154; called by muse, mutect2, varscan2
- OR5J2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364673970, COSV56620315; called by muse, mutect2, varscan2
- OR5M1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV73202071; called by muse, mutect2, varscan2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OR6C3 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV65571991; called by muse, mutect2, varscan2
- OR6C6 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV64456025; called by muse, mutect2, varscan2
- OR6C70 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV59245343; called by muse, mutect2, varscan2
- OR8B12 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs1378778291, COSV60912714; called by muse, mutect2, varscan2
- OR8S1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59599496, COSV59599766; called by muse, mutect2, varscan2
- OR8U1 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as COSV56418443; called by muse, varscan2
- ORMDL3 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.999); catalogued as COSV58346481; called by mutect2, varscan2
- ORMDL3 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as COSV100401597; called by muse, mutect2, varscan2
- OSBP2 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1208609404, COSV60248155; called by muse, mutect2, varscan2
- OSBPL3 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs374921777, COSV57652693; called by muse, mutect2, varscan2
- OTOGL | c.3464C>T p.S1155F (on ENST00000547103; = p.S1146F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV72006454, COSV72007374; called by muse, mutect2, varscan2
- OTOL1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as COSV60008299; called by muse, mutect2, varscan2
- PADI6 | c.100T>G p.C34G | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.098); catalogued as COSV61885633; called by muse, mutect2, varscan2
- PAN2 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV57755754; called by muse, mutect2, varscan2
- PAPOLB | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV68203286; called by muse, mutect2, varscan2
- PARD6G | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100783489; called by muse, mutect2, varscan2
- PCARE | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs1381872170, COSV59057604; called by muse, mutect2, varscan2
- PCDHA9 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.417); catalogued as rs781937410, COSV65331908; called by muse, mutect2, varscan2
- PCDHB6 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs782536394, COSV50690800; called by muse, mutect2, varscan2
- PCDHB7 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781810804, COSV50796991, COSV50808733; called by muse, mutect2, varscan2
- PCDHB8 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 60/318 reads (19%) | catalogued as rs782574862, COSV50796454; called by muse, mutect2, varscan2
- PCDHB9 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554282883, COSV53383064; called by muse, mutect2, varscan2
- PCDHGA1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.624); catalogued as rs1425911042, COSV65295151; called by muse, mutect2, varscan2
- PCDHGA1 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65296795; called by muse, mutect2, varscan2
- PCDHGA1 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.334); catalogued as COSV100966142; called by muse, mutect2, varscan2
- PCDHGA2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54018288; called by muse, mutect2, varscan2
- PCDHGA8 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); catalogued as COSV54012878; called by muse, mutect2, varscan2
- PCDHGB3 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.321); catalogued as COSV54018305; called by muse, mutect2, varscan2
- PCED1A | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV62314135; called by muse, mutect2, varscan2
- PDE1A | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV59534467; called by muse, mutect2, varscan2
- PDGFC | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56854037; called by muse, mutect2, varscan2
- PDZD4 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.7); catalogued as COSV51245317; called by muse, mutect2, varscan2
- PDZRN4 | c.2662G>A p.E888K (on ENST00000402685 / NM_001164595.2; = p.E630K on NM_013377.4) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54215018; called by muse, mutect2, varscan2
- PELI2 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99954052; called by muse, mutect2, varscan2
- PGAP4 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs761936237, COSV66388315; called by muse, mutect2, varscan2
- PGLYRP4 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV62836222; called by muse, mutect2, varscan2
- PHACTR1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV100279082; called by muse, mutect2, varscan2
- PHIP | c.3623C>T p.T1208I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51509565; called by muse, mutect2, varscan2
- PIGQ | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50319721; called by muse, mutect2, varscan2
- PIK3C2B | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV65804177; called by muse, mutect2, varscan2
- PINK1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as COSV58632722; called by muse, mutect2, varscan2
- PKD1L2 | c.178G>T p.G60* | Nonsense Mutation (SNP) | VAF 31/47 reads (66%) | catalogued as COSV61419060; called by muse, mutect2, varscan2
- PKMYT1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV51892672; called by muse, mutect2, varscan2
- PKP4 | c.2672C>T p.S891F | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61580180; called by muse, mutect2, varscan2
- PLA2G4A | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); catalogued as rs1360297970, COSV66556457; called by muse, mutect2, varscan2
- PLAAT3 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV60312585; called by muse, varscan2
- PLCD4 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV68843302; called by muse, mutect2, varscan2
- PLEC | c.1357-1G>A p.X453_splice (on ENST00000322810 / NM_201380.4; = p.X343_splice on NM_000445.5) | Splice Site (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100519689; called by muse, mutect2, varscan2
- PLEKHG4B | c.2200C>T p.Q734* (on ENST00000283426; = p.Q1090* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 59/168 reads (35%) | catalogued as COSV52053983; called by muse, mutect2, varscan2
- PLPPR3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1030313837, COSV62461567; called by muse, mutect2, varscan2
- PLPPR4 | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV64567526; called by muse, mutect2, varscan2
- PLXDC1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV59553550; called by muse, mutect2, varscan2
- PLXNB1 | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56493685; called by muse, mutect2, varscan2
- PLXNB3 | c.4672C>T p.Q1558* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV62801504; called by muse, mutect2
- POLD3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV55245420; called by muse, mutect2, varscan2
- POLG | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as rs369175235, COSV51524798; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3B | c.3095C>T p.T1032I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57283826; called by muse, mutect2, varscan2
- PORCN | c.749C>T p.S250F (on ENST00000326194 / NM_203475.3; = p.S239F on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58227067; called by muse, mutect2, varscan2
- POTEF | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV62543716; called by muse, mutect2, varscan2
- POU3F4 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV64540794; called by muse, mutect2, varscan2
- PPARG | c.1114G>A p.G372S (on ENST00000287820 / NM_015869.5; = p.G342S on NM_005037.7) | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs1273044250, COSV55145015; called by muse, mutect2, varscan2
- PPARGC1B | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV58532643; called by muse, mutect2, varscan2
- PPARGC1B | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58532651; called by muse, mutect2
- PPP1R12B | c.1553T>G p.V518G | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61122894; called by muse, mutect2, varscan2
- PPP1R3D | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100674685; called by muse, mutect2, varscan2
- PRB3 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs905255477, COSV54393040; called by muse, mutect2, varscan2
- PRDM5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs142855444; called by muse, mutect2, varscan2
- PRELP | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557976, COSV58115580; called by muse, mutect2, varscan2
- PRELP | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58117807; called by muse, mutect2, varscan2
- PRICKLE1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV61546284; called by muse, mutect2, varscan2
- PRKAG3 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs370008874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR14 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1353512207, COSV54913478; called by muse, mutect2, varscan2
- PRR35 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.105); catalogued as rs1429389066, COSV50319689; called by muse, mutect2, varscan2
- PRR5L | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV61123258; called by muse, mutect2, varscan2
- PRRC2A | c.3007C>T p.L1003F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV65686349, COSV65688705; called by muse, mutect2, varscan2
- PRSS37 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV63340046; called by muse, mutect2, varscan2
- PRX | c.4193C>T p.A1398V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as CM1410217, COSV52519569, COSV52519595; called by muse, mutect2, varscan2
- PTGER1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV52876331; called by muse, mutect2
- PTK2B | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs762788059, COSV100594348, COSV57764928; called by muse, mutect2, varscan2
- PTK6 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53918301; called by muse, mutect2, varscan2
- PTPN22 | c.2078C>T p.P693L (on ENST00000359785 / NM_001193431.2; = p.P638L on NM_012411.5) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs763836317, COSV63086358; called by muse, mutect2, varscan2
- PTPRB | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54232063; called by muse, mutect2, varscan2
- RAB40A | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1221413109, COSV58491738; called by muse, varscan2
- RADIL | c.1966G>A p.G656S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67651006; called by muse, mutect2, varscan2
- RASGRF1 | c.2798T>A p.F933Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV67251062; called by muse, mutect2, varscan2
- RCAN3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV65558938; called by muse, mutect2, varscan2
- RDH8 | c.559G>A p.E187K (on ENST00000651512; = p.E167K on NM_015725.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755753285, COSV50674103; called by muse, mutect2, varscan2
- REL | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV54366986; called by muse, mutect2, varscan2
- RELCH | c.1621-1G>A p.X541_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV56891402; called by muse, mutect2, varscan2
- RELCH | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99902889; called by muse, mutect2, varscan2
- RGS7 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV58558022; called by muse, mutect2, varscan2
- RHOBTB1 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61959975; called by muse, mutect2, varscan2
- RIN1 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV60928553; called by muse, mutect2
- RNF169 | c.2108A>G p.N703S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55135296; called by muse, mutect2, varscan2
- ROBO2 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs779554773, COSV59934368; called by muse, mutect2, varscan2
- RP1 | c.5095G>A p.E1699K | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV55125097; called by muse, mutect2, varscan2
- RPS6KA2 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV55828169; called by muse, mutect2, varscan2
- RPTN | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 183/512 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768986867, COSV60166732; called by muse, mutect2, varscan2
- RTL3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs754780962, COSV100329782, COSV58183264; called by muse, mutect2, varscan2
- RTL4 | c.290A>T p.K97I | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV61207234; called by muse, mutect2, varscan2
- RUNDC3A | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1159468963, COSV99842093; called by muse, mutect2, varscan2
- RUNDC3A | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV99842096; called by muse, mutect2, varscan2
- RYR1 | c.12335C>T p.S4112L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs193922847, CM071983, COSV62087989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAGE1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 117/259 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1265362591, COSV61017095; called by muse, mutect2, varscan2
- SAMD9L | c.3350C>T p.S1117F | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59079287; called by muse, mutect2, varscan2
- SATB1 | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as COSV58672284; called by muse, mutect2, varscan2
- SBF2 | c.2059T>G p.S687A | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.156); catalogued as COSV56305776; called by muse, mutect2, varscan2
- SCN5A | c.3232G>A p.E1078K (on ENST00000333535 / NM_198056.3; = p.E1077K on NM_000335.5) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.973); catalogued as COSV61138938; called by muse, mutect2, varscan2
- SCN7A | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.459); catalogued as rs970770597, COSV69267984; called by muse, mutect2
- SCN7A | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); catalogued as COSV69268350, COSV69274269; called by muse, mutect2
- SCN9A | c.2399C>T p.P800L (on ENST00000303354; = p.P789L on NM_002977.3) | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57621937; called by muse, mutect2, varscan2
- SDK1 | c.4234C>T p.Q1412* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV67386134; called by muse, mutect2, varscan2
- SEC23B | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs772402564, COSV52722725; called by muse, mutect2, varscan2
- SELENOP | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs764096154, COSV62793318; called by muse, mutect2, varscan2
- SELL | c.469G>A p.D157N (on ENST00000650983; = p.D144N on NM_000655.5) | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52550157; called by muse, mutect2, varscan2
- SELP | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55257590; called by muse, mutect2, varscan2
- SEMA5B | c.89G>A p.W30* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as rs1410882732, COSV52106767; called by muse, mutect2, varscan2
- SEMA6A | c.2864G>A p.R955K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs1439501136, COSV56714440; called by muse, mutect2, varscan2
- SEMA6D | c.2428C>T p.P810S (on ENST00000316364 / NM_153618.2; = p.P748S on NM_020858.2) | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.642); catalogued as COSV60382948; called by muse, mutect2, varscan2
- SENP2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV56192776, COSV99958303; called by muse, mutect2, varscan2
- SERPINA11 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as COSV58241685; called by muse, mutect2, varscan2
- SERPINA3 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV67587027; called by muse, mutect2, varscan2
- SERPINA9 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV54074570; called by muse, mutect2, varscan2
- SETBP1 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56319457; called by muse, mutect2, varscan2
- SETD1A | c.3007G>T p.V1003L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV52691837; called by muse, mutect2, varscan2
- SF1 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV57116990; called by muse, mutect2, varscan2
- SGCZ | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 226/570 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.347); catalogued as rs760258085, COSV66039778; called by muse, mutect2, varscan2
- SGIP1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV52777591; called by muse, mutect2, varscan2
- SGIP1 | c.1127T>C p.L376S | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.038); catalogued as COSV52777604; called by muse, mutect2, varscan2
- SGO1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV55424942, COSV99768384; called by muse, mutect2, varscan2
- SGSM2 | c.1436C>T p.P479L (on ENST00000426855 / NM_001098509.2; = p.P524L on NM_014853.3) | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99280625; called by muse, mutect2, varscan2
- SH3RF2 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV63041071; called by muse, mutect2, varscan2
- SHANK1 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as COSV53241948; called by muse, mutect2, varscan2
- SHANK1 | c.2424G>A p.M808I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV99522078; called by muse, mutect2, varscan2
- SHROOM4 | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99174834; called by muse, mutect2, varscan2
- SIDT1 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as COSV53506355; called by muse, mutect2, varscan2
- SIDT2 | c.2482A>T p.K828* | Nonsense Mutation (SNP) | VAF 62/138 reads (45%) | catalogued as COSV54060202; called by muse, mutect2, varscan2
- SIGLEC5 | c.1172G>A p.W391* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV55783043; called by muse, mutect2, varscan2
- SIGLEC6 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV58437059; called by muse, mutect2, varscan2
- SIPA1L1 | c.4867C>T p.P1623S | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.492); catalogued as COSV62173134; called by muse, mutect2, varscan2
- SKA3 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV53436756; called by muse, mutect2, varscan2
- SLAMF6 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); catalogued as rs771240749, COSV100924864, COSV63587736; called by muse, mutect2, varscan2
- SLC10A3 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1557213698, COSV54836049; called by muse, mutect2, varscan2
- SLC17A8 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1410781085, COSV60126137; called by muse, mutect2, varscan2
- SLC1A2 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV53525390; called by muse, mutect2, varscan2
- SLC22A9 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54169839; called by muse, mutect2, varscan2
- SLC24A2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV53866898; called by muse, mutect2, varscan2
- SLC24A3 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs1317802795, COSV60130170; called by muse, mutect2, varscan2
- SLC25A24 | c.886T>C p.S296P | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV51450328; called by muse, mutect2, varscan2
- SLC2A2 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.153); catalogued as rs144822218, COSV100049387, COSV100049461; called by muse, mutect2, varscan2
- SLC34A2 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101158471; called by muse, mutect2, varscan2
- SLC34A2 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101158472, COSV65942017; called by muse, mutect2, varscan2
- SLC35A4 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as COSV60054014; called by muse, mutect2, varscan2
- SLC6A13 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as rs919418984, COSV58259943; called by muse, mutect2, varscan2
- SLC6A6 | c.1533C>G p.I511M | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV62652292; called by muse, mutect2, varscan2
- SLC7A3 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV53229118; called by muse, mutect2, varscan2
- SLCO1C1 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV56878843; called by muse, mutect2, varscan2
- SLIT2 | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV56574824; called by muse, mutect2, varscan2
- SLITRK3 | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV53852700, COSV99579538; called by muse, mutect2, varscan2
- SLMAP | c.1345G>A p.E449K (on ENST00000428312 / NM_001377924.1; = p.E511K on NM_007159.5) | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as rs1409531494, COSV55852421; called by muse, mutect2, varscan2
- SLPI | c.144A>T p.K48N | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.773); catalogued as COSV58092621; called by muse, mutect2, varscan2
- SMARCC1 | c.539T>C p.L180S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54385731; called by muse, mutect2, varscan2
- SMOC1 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764074930, COSV62762334; called by muse, mutect2, varscan2
- SNED1 | c.2791G>A p.G931S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs772020074, COSV60032414; called by muse, mutect2, varscan2
- SORCS2 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs747884144, COSV61162520; called by muse, mutect2, varscan2
- SOX8 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288476638, COSV53510495; called by muse, mutect2, varscan2
- SOX9 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.214); catalogued as rs1249311365, COSV55427905; called by muse, mutect2, varscan2
- SPACA3 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV52192471; called by muse, mutect2, varscan2
- SPANXN3 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV65139916; called by muse, mutect2, varscan2
- SPATC1L | c.722C>T p.S241F (on ENST00000291672 / NM_001142854.2; = p.S87F on NM_032261.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs750576865, COSV52434581; called by muse, mutect2
- SPEF2 | c.4285T>A p.Y1429N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV57431926; called by muse, mutect2, varscan2
- SPHK1 | c.1035G>A p.M345I (on ENST00000392496 / NM_001355139.2; = p.M359I on NM_021972.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100039412, COSV60067150; called by muse, mutect2, varscan2
- SPTA1 | c.267G>A p.G89= | Splice Region (SNP) | VAF 33/86 reads (38%) | catalogued as rs973802070, COSV63751889; called by muse, mutect2, varscan2
- SPTB | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs976130875, COSV67633194; called by muse, mutect2, varscan2
- SPTBN2 | c.5770G>A p.D1924N | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV59460210; called by muse, mutect2, varscan2
- SRRM1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV60480321; called by muse, mutect2, varscan2
- SRRM2 | c.7664C>T p.S2555F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs141595233, COSV51940641; called by muse, mutect2, varscan2
- SSH1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100425862, COSV100425877; called by muse, mutect2, varscan2
- SSH1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs373198617, COSV100425388, COSV58460638; called by muse, mutect2, varscan2
- SSPOP | n.1910G>A | Splice Region (SNP) | VAF 24/69 reads (35%) | catalogued as rs1382933162, COSV50489134; called by muse, mutect2, varscan2
- ST6GAL1 | c.495G>A p.W165* | Nonsense Mutation (SNP) | VAF 32/114 reads (28%) | catalogued as COSV99399733; called by muse, mutect2, varscan2
- ST6GAL1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 32/113 reads (28%) | PolyPhen benign (0.026); catalogued as COSV99399736; called by muse, mutect2, varscan2
- STEAP1 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 133/232 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51882671; called by muse, mutect2, varscan2
- STIL | c.1363T>A p.L455M | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV54553098; called by muse, mutect2, varscan2
- STK40 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs1356391159, COSV100828758; called by muse, varscan2
- STK40 | c.345C>T p.D115= | Splice Region (SNP) | VAF 45/137 reads (33%) | catalogued as COSV63736412; called by muse, varscan2
- STXBP5L | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.424); catalogued as COSV56531781; called by muse, mutect2, varscan2
- STYXL2 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99608621, COSV99609974; called by muse, mutect2, varscan2
- SULT2B1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs1040692276, COSV52378458; called by muse, mutect2
- SULT6B1 | c.907G>A p.G303S (on ENST00000535679 / NM_001367551.1; = p.G265S on NM_001032377.2) | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53195924; called by muse, mutect2, varscan2
- SYCP2 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376223827; called by muse, mutect2, varscan2
- SYNE1 | c.22637G>A p.G7546E (on ENST00000367255 / NM_182961.4; = p.G7475E on NM_033071.3) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55081804; called by muse, mutect2, varscan2
- SYNE1 | c.1510G>A p.E504K (on ENST00000367255 / NM_182961.4; = p.E511K on NM_033071.3) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV55081837; called by muse, mutect2, varscan2
- SYNE2 | c.4943G>A p.W1648* | Nonsense Mutation (SNP) | VAF 58/182 reads (32%) | catalogued as COSV59967146; called by muse, mutect2, varscan2
- SYNJ1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as rs1487423508, COSV59155461; called by muse, mutect2, varscan2
- SYNPO2 | c.3771G>A p.W1257* | Nonsense Mutation (SNP) | VAF 38/91 reads (42%) | catalogued as COSV61115938; called by muse, mutect2, varscan2
- SYT1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138582600, COSV54034805; called by muse, mutect2, varscan2
- SYT1 | c.728A>G p.E243G | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54070280; called by muse, mutect2, varscan2
- SYT8 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53290921; called by muse, mutect2, varscan2
- SYTL4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1436858943, COSV52166250; called by muse, mutect2, varscan2
- TBX22 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64786243, COSV64787629; called by muse, mutect2, varscan2
- TCEAL1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.271); catalogued as COSV101010099, COSV65461283; called by muse, mutect2, varscan2
- TCEAL8 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs770282422, COSV63506612; called by muse, mutect2, varscan2
- TENM4 | c.2364C>T p.I788= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as rs766854452, COSV53663823; called by muse, mutect2
- TENT5D | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV57638879; called by muse, mutect2, varscan2
- TERB2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV61650558; called by muse, mutect2, varscan2
- TF | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53923635, COSV99396565; called by muse, mutect2, varscan2
- TGFBR2 | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.084); catalogued as rs768103695, COSV99848284; called by muse, mutect2, varscan2
- TGFBR2 | c.1682G>A p.G561D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.084); catalogued as COSV55449556, COSV99848286; called by muse, mutect2, varscan2
- TH | c.1282G>A p.G428R (on ENST00000381178 / NM_199292.3; = p.G397R on NM_000360.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1264884607, CM126822, COSV51747680, COSV51748270; called by muse, mutect2, varscan2
- THOC2 | c.4481C>T p.P1494L | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1462611888, COSV55551216; called by muse, mutect2, varscan2
- THRB | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs760749837, COSV62841365; called by muse, mutect2, varscan2
- TIAM2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100020363, COSV59697022; called by muse, mutect2, varscan2
- TIPIN | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.089); catalogued as COSV56020896; called by muse, mutect2, varscan2
- TLN2 | c.4063T>A p.C1355S | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100170235; called by muse, mutect2, varscan2
- TM4SF4 | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59516903; called by muse, mutect2, varscan2
- TMC5 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.177); catalogued as COSV66868410; called by muse, mutect2, varscan2
- TMEM131L | c.2049G>T p.L683F | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV53649631; called by muse, mutect2, varscan2
- TMEM156 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.282); catalogued as COSV67930016; called by muse, mutect2, varscan2
- TMEM164 | c.604C>T p.P202S (on ENST00000372068 / NM_032227.4; = p.P53S on NM_017698.2) | Missense Mutation (SNP) | VAF 181/527 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as rs1373140486, COSV99912186; called by muse, mutect2, varscan2
- TMEM164 | c.605C>T p.P202L (on ENST00000372068 / NM_032227.4; = p.P53L on NM_017698.2) | Missense Mutation (SNP) | VAF 170/502 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99912192; called by muse, varscan2
- TMEM270 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV57637996; called by muse, mutect2, varscan2
- TMEM59 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV52375696, COSV52376290; called by muse, mutect2, varscan2
- TMEM72 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs377099938; called by muse, mutect2, varscan2
- TMPRSS11D | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52225739; called by muse, mutect2, varscan2
- TMPRSS11E | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 140/420 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs145801188; called by muse, mutect2, varscan2
- TMPRSS7 | c.956A>G p.Y319C (on ENST00000452346; = p.Y193C on NM_001042575.2) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV69982372; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.575T>A p.I192N | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV59529382; called by muse, mutect2, varscan2
- TNFRSF8 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV55800096; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1952T>G p.V651G | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV64102413; called by muse, mutect2, varscan2
- TNN | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53428877, COSV99511224; called by muse, mutect2, varscan2
- TNR | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1197267240, COSV54909265; called by muse, mutect2, varscan2
- TNRC6B | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV57295864; called by muse, mutect2, varscan2
- TNXB | c.9118G>A p.G3040S (on ENST00000647633; = p.G2793S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV64487837; called by muse, mutect2, varscan2
- TNXB | c.6223G>A p.E2075K (on ENST00000647633; = p.E1828K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); catalogued as rs1221905399, COSV64487847; called by muse, mutect2, varscan2
- TP53BP1 | c.4199G>A p.R1400Q | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55507916; called by muse, mutect2, varscan2
- TP53BP2 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757047375, COSV100636501, COSV100636839; called by muse, mutect2, varscan2
- TP63 | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs865905084, COSV53218990; called by muse, mutect2, varscan2
- TRIM17 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV52859805; called by muse, mutect2, varscan2
- TRIM32 | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as COSV57812789; called by muse, mutect2, varscan2
- TRIP6 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV51933581, COSV51936572; called by muse, mutect2
- TRMT12 | c.417T>A p.N139K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV60777824; called by muse, mutect2, varscan2
- TRPC4 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV59000571; called by muse, mutect2, varscan2
- TRPC5 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53301532; called by muse, mutect2, varscan2
- TRPV6 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV63892840; called by muse, mutect2, varscan2
- TRRAP | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV62852943; called by muse, mutect2, varscan2
- TSC22D3 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.809); catalogued as COSV100227042; called by muse, mutect2, varscan2
- TSHR | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as rs746685925, COSV53322585; called by muse, mutect2, varscan2
- TSHR | c.1559G>A p.W520* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as CM094316, COSV53330095; called by muse, mutect2, varscan2
- TTC13 | c.1966C>T p.L656F | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV100793051; called by muse, mutect2, varscan2
- TTC38 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs370235291; called by muse, mutect2, varscan2
- TTN | c.46121C>T p.P15374L (on ENST00000591111; = p.P7950L on NM_003319.4) | Missense Mutation (SNP) | VAF 37/72 reads (51%) | PolyPhen benign (0.001); catalogued as COSV60299277; called by muse, mutect2, varscan2
- TUBA1B | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV100254237; called by muse, mutect2, varscan2
- TUBA3C | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as rs868127144, COSV68029500; called by muse, mutect2, varscan2
- TUBB4A | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.292); catalogued as COSV51164090, COSV99900116; called by muse, mutect2, varscan2
- TUBB6 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52316983; called by muse, mutect2, varscan2
- U2SURP | c.825T>G p.N275K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67532912; called by muse, mutect2, varscan2
456 further variants in this file (75 protein-altering or splice-affecting, 361 silent, 20 other) are not listed here.
